Somatic mutation profile of tumor specimen ALCH-AE13-TTP1-A (aliquot ALCH-AE13-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE13, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.5 years (22,465 days).
Specimen ALCH-AE13-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a63a91a4-858c-4d10-8310-1eea41fd9c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE13-NB1-A (Blood Derived Normal), aliquot ALCH-AE13-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d113c8d3-d814-4f4f-909d-7efea490c982

The open-access MAF lists 617 somatic variants for this specimen: 408 protein-altering or splice-affecting, 140 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 350, Silent 140, Nonsense Mutation 31, Intron 30, RNA 15, Frame Shift Del 13, 3'UTR 11, 5'UTR 7, Splice Site 6, Splice Region 4, 3'Flank 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 46/208 reads (22%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- DYRK1A | c.1333dup p.T445Nfs*4 | Frame Shift Ins (INS) | VAF 46/524 reads (9%) | catalogued as rs1555990855; ClinVar: pathogenic; called by mutect2, pindel
- HCN1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 56/816 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561081319, COSV57492050; ClinVar: pathogenic; called by muse, mutect2
- MME | c.655-2A>G p.X219_splice | Splice Site (SNP) | VAF 46/524 reads (9%) | catalogued as rs765591205, CS164263; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 62/341 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 42/245 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1208C>A p.A403E (on ENST00000373993 / NM_138932.2; = p.A395E on NM_014576.4) | Missense Mutation (SNP) | VAF 36/506 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV50963517; called by muse, mutect2
- ACADSB | c.1228G>C p.G410R | Missense Mutation (SNP) | VAF 60/632 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CS002875; called by muse, mutect2
- ACOXL | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as COSV100490279; called by muse, mutect2, varscan2
- ADAMTS18 | c.2587G>A p.V863I | Missense Mutation (SNP) | VAF 76/687 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs757868461; called by muse, mutect2, varscan2
- ADAMTS20 | c.2816G>C p.G939A | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV67129016; called by muse, mutect2
- ADGRL2 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 46/673 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as COSV54652743; called by muse, mutect2
- ADGRL4 | c.461T>A p.L154H | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV66060725; called by muse, mutect2
- ADIPOR1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100579505; called by muse, mutect2
- AKAP6 | c.1783G>T p.V595L | Missense Mutation (SNP) | VAF 46/599 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1247036566; called by muse, mutect2
- AMPH | c.1189G>C p.G397R | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV100343647; called by muse, mutect2
- ANKRD45 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 25/485 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100322564; called by muse, mutect2
- ARHGEF10L | c.3752G>A p.G1251D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as rs1249645374; called by muse, mutect2, varscan2
- ASPM | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 95/633 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV54126462; called by muse, mutect2, varscan2
- ASTN1 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV56066520; called by muse, mutect2
- ATP10A | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100790714; called by muse, mutect2, varscan2
- ATP10D | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs528576045, COSV56705850; called by muse, mutect2, varscan2
- ATP1B4 | c.1002A>T p.K334N (on ENST00000218008 / NM_001142447.3; = p.K330N on NM_012069.5) | Missense Mutation (SNP) | VAF 14/359 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.31); catalogued as COSV54311311; called by muse, mutect2
- BCHE | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 65/704 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs890798673; called by muse, mutect2
- BRINP3 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV66515742, COSV66535700; called by muse, mutect2
- C12orf56 | c.1625G>A p.G542D (on ENST00000543942 / NM_001170633.2; = p.G382D on NM_001099676.3) | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs1465491690; called by muse, mutect2
- C1QTNF12 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs868337477; called by muse, mutect2, varscan2
- CCDC160 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV66251626; called by muse, mutect2, varscan2
- CHM | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 89/658 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs781303756, COSV63303110; called by muse, mutect2, varscan2
- COL6A5 | c.6719T>C p.F2240S (on ENST00000312481; = p.F2236S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/866 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs781305298; called by muse, mutect2
- COL6A6 | c.4426G>A p.G1476S | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383569505, COSV100651188, COSV100651208; called by muse, mutect2
- CRACD | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770975009; called by muse, mutect2, varscan2
- CROCC2 | c.1674G>C p.E558D | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1407303106; called by muse, mutect2
- CSMD2 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs756045595, COSV99592111; called by muse, mutect2
- CSMD3 | c.4306G>A p.D1436N (on ENST00000297405 / NM_001363185.1; = p.D1332N on NM_052900.3) | Missense Mutation (SNP) | VAF 30/861 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52095707, COSV52154546; called by muse, mutect2
- CUZD1 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1384986887; called by muse, mutect2, varscan2
- CWC27 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1561406016; called by muse, mutect2
- DNAH10 | c.1009C>T p.P337S (on ENST00000409039; = p.P276S on NM_207437.3) | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749055036; called by muse, mutect2, varscan2
- DNAH3 | c.8747C>A p.A2916D | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV99770240; called by muse, mutect2, varscan2
- DNAH5 | c.9481G>A p.V3161I | Missense Mutation (SNP) | VAF 54/835 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs773045896; called by muse, mutect2
- DPYD | c.379G>T p.G127* | Nonsense Mutation (SNP) | VAF 46/430 reads (11%) | catalogued as COSV60079571; called by muse, mutect2
- FAAH2 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV66509598; called by muse, mutect2
- FBN1 | c.4895G>T p.R1632L | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as CM096453, COSV57321219, COSV57328992; called by muse, mutect2
- FERD3L | c.272del p.R91Pfs*7 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | catalogued as COSV51763141, COSV51764984; called by mutect2, pindel, varscan2
- FMR1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 55/387 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1557174007; called by muse, mutect2, varscan2
- FURIN | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99184764; called by muse, mutect2, varscan2
- FUT9 | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100132779; called by muse, mutect2
- GABRA1 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV50101290; called by muse, mutect2, varscan2
- GABRB1 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752134548, COSV99780572; called by muse, mutect2
- GLB1L3 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs987685428, COSV101111056; called by muse, mutect2, varscan2
- GOLGB1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 26/591 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747227059, COSV61463800; called by muse, mutect2
- GPR150 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs778497974; called by mutect2, varscan2
- GUCY1A2 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as rs1263876712; called by muse, mutect2
- HDAC9 | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67781384; called by muse, mutect2
- HMGCL | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); catalogued as rs1040895585; called by muse, mutect2
- HNRNPM | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57692704; called by muse, mutect2
- HOXD3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs943267376; called by muse, mutect2
- HRNR | c.1578A>C p.Q526H | Missense Mutation (SNP) | VAF 36/540 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.79); catalogued as rs751303452, COSV64257895; called by muse, mutect2
- HS3ST4 | c.535G>C p.G179R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.25); catalogued as rs538838952; called by muse, mutect2, varscan2
- IGKV1D-17 | c.348C>A p.Y116* | Nonsense Mutation (SNP) | VAF 50/396 reads (13%) | catalogued as rs1354651273; called by muse, mutect2, varscan2
- ITGB4 | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs922261568, COSV52334658; called by muse, mutect2
- ITIH5 | c.1683G>T p.R561S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV99905551; called by muse, mutect2
- KIAA1109 | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52666211; called by muse, mutect2
- KIF2B | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774243494, COSV52133143, COSV52136687; called by muse, mutect2
- KIF2B | c.1967A>G p.Q656R | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748671283, COSV52127958; called by muse, mutect2, varscan2
- KIF4B | c.3560C>A p.P1187H | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.179); catalogued as rs758739235; called by muse, mutect2
- KIF5A | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772697257, COSV99673740; called by muse, mutect2
- KLHL4 | c.1406T>A p.F469Y | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64149033; called by muse, mutect2, varscan2
- LPP | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 109/598 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57078977; called by muse, mutect2, varscan2
- LRP1B | c.6179G>T p.R2060L | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV67283743, COSV67287558; called by muse, mutect2
- LRRTM4 | c.719G>T p.R240M | Missense Mutation (SNP) | VAF 60/410 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs866600882, COSV101297619, COSV69141284; called by muse, mutect2, varscan2
- LSR | c.1556_1557insGAA p.R519_S520insK (on ENST00000361790; = p.R500_S501insK on NM_015925.6) | In Frame Ins (INS) | VAF 14/65 reads (22%) | catalogued as COSV55886347, COSV55886449, COSV55888201; called by mutect2, pindel
- MAGEC1 | c.1727C>A p.S576Y | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV53569129, COSV53574680; called by muse, mutect2, varscan2
- MAGED1 | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1557363875; called by muse, mutect2
- MC2R | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 103/735 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as rs769721256, COSV59620712; called by muse, mutect2, varscan2
- MMS22L | c.1649A>G p.H550R | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775082957; called by muse, mutect2
- MORC1 | c.2046G>T p.W682C | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV51722093, COSV51732092; called by muse, mutect2
- MPEG1 | c.367T>A p.S123T | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); catalogued as rs200960951; called by muse, mutect2
- MPP4 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs375529816; called by muse, mutect2, varscan2
- MS4A6E | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 48/579 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55726620; called by muse, mutect2
- MUC16 | c.43114G>A p.D14372N | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs1220130348; called by muse, mutect2
- MYCT1 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.744); catalogued as COSV65891662; called by muse, mutect2
- MYPN | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 62/840 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs764042082, COSV62735955; called by muse, mutect2
- NME7 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV63168064; called by muse, mutect2
- NPHS1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100800261; called by muse, mutect2, varscan2
- NRXN1 | c.3773A>G p.E1258G | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1443763335; called by muse, mutect2
- OR10J5 | c.710T>C p.F237S | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750911188; called by muse, mutect2
- OR11L1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869509, COSV99053953; called by muse, mutect2, varscan2
- OR4S2 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs779832920; called by muse, mutect2, varscan2
- OR5T3 | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 40/499 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100282756; called by muse, mutect2
- P3H1 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV52531886; called by muse, mutect2, varscan2
- PASD1 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as COSV100949717; called by muse, mutect2, varscan2
- PCDH10 | c.1612G>T p.D538Y | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs568804747, COSV52092296, COSV52092303, COSV52094318; called by muse, mutect2
- PCDHA2 | c.1945G>C p.V649L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.776); catalogued as rs782163071, COSV65366037; called by muse, mutect2
- PCDHAC1 | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53838602, COSV53862217; called by muse, mutect2, varscan2
- PDE10A | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 68/443 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as COSV100605068; called by muse, mutect2, varscan2
- PDZRN4 | c.1299C>A p.S433R (on ENST00000402685 / NM_001164595.2; = p.S175R on NM_013377.4) | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54192722, COSV54197111; called by muse, mutect2, varscan2
- PHYHIPL | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as rs761450894; called by muse, mutect2
- PITRM1 | c.2931C>G p.F977L | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56528966; called by muse, mutect2
- PLG | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs750784310; called by muse, mutect2, varscan2
- PNLIP | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs373869947; called by muse, mutect2
- PPRC1 | c.3388C>T p.P1130S | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1439785492; called by muse, mutect2, varscan2
- PRDX4 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1242604347; called by muse, varscan2
- PRDX4 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.025); catalogued as rs1466134181; called by muse, varscan2
- PREX2 | c.1443G>T p.K481N | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1186603196, COSV55782126; called by muse, mutect2, varscan2
- PRRG1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 23/294 reads (8%) | catalogued as COSV101069009; called by muse, mutect2
- PXDN | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV53238198; called by muse, mutect2, varscan2
- RCAN2 | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 68/538 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1185467748; called by muse, mutect2, varscan2
- RGPD3 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs753864926; called by muse, mutect2, varscan2
- RYR2 | c.7404G>T p.M2468I | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV63719573; called by muse, mutect2, varscan2
- SDK1 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as rs780195495; called by muse, mutect2, varscan2
- SDK1 | c.4139C>G p.P1380R | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749738707; called by muse, mutect2, varscan2
- SEMA6D | c.2438C>T p.P813L (on ENST00000316364 / NM_153618.2; = p.P751L on NM_020858.2) | Missense Mutation (SNP) | VAF 104/628 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs746411921, COSV100317541; called by muse, varscan2
- SHROOM2 | c.3932T>C p.V1311A | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1272450513; called by muse, mutect2
- SLC27A1 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs1291266470; called by muse, mutect2
- SLC8A1 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100245852; called by muse, mutect2
- SLITRK2 | c.939del p.R314Efs*2 | Frame Shift Del (DEL) | VAF 58/406 reads (14%) | catalogued as rs868910583, COSV59422724; called by mutect2, pindel, varscan2
- SMAD3 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 73/713 reads (10%) | catalogued as rs1458265923; called by muse, mutect2, varscan2
- SORCS3 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100864408, COSV100865322; called by muse, mutect2
- SPPL2B | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs777508107, COSV66317296; called by muse, mutect2
- TANGO2 | c.649G>C p.V217L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.133); catalogued as COSV59294109; called by muse, mutect2, varscan2
- TCF7L2 | c.1251G>A p.W417* (on ENST00000355995 / NM_001367943.1; = p.W394* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 17/140 reads (12%) | catalogued as COSV53336087; called by muse, varscan2
- TDRD15 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1350114279; called by muse, mutect2, varscan2
- TECRL | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 63/608 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV67088066; called by muse, mutect2, varscan2
- TIMP2 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV53161968; called by muse, mutect2, varscan2
- TLE6 | c.780G>T p.R260S (on ENST00000246112 / NM_001143986.2; = p.R137S on NM_024760.3) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV55736845; called by muse, varscan2
- TRABD2A | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59105537; called by muse, mutect2, varscan2
- TRAV4 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 32/612 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1423126047; called by muse, mutect2
- TRIM48 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 33/583 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1295582029, COSV70162220; called by muse, mutect2
- TTN | c.62339G>A p.G20780E (on ENST00000591111; = p.G13356E on NM_003319.4) | Missense Mutation (SNP) | VAF 50/548 reads (9%) | PolyPhen probably damaging (1); catalogued as COSV100631007, COSV59942139; called by muse, mutect2
- TTN | c.43388A>T p.K14463I (on ENST00000591111; = p.K7039I on NM_003319.4) | Missense Mutation (SNP) | VAF 22/253 reads (9%) | PolyPhen probably damaging (0.925); catalogued as COSV59869410; called by muse, mutect2
- ZBP1 | c.794A>C p.Q265P | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59060330; called by muse, mutect2
- ZNF521 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs1181328543; called by muse, mutect2, varscan2
- ZNF536 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62821888; called by muse, mutect2, varscan2
- ZNF717 | c.2245C>A p.H749N | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV101277392; called by muse, mutect2
- ZNF814 | c.1901G>A p.C634Y | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1029349301; called by muse, mutect2, varscan2
- ABCC4 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 23/281 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- ABCC8 | c.1327G>T p.V443L | Missense Mutation (SNP) | VAF 59/392 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AC099489.1 | c.3469G>T p.E1157* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- ACIN1 | c.769A>T p.R257* | Nonsense Mutation (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- ACKR4 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 103/764 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM1 | c.896C>G p.T299S | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.131); called by muse, mutect2
- ACTN4 | c.1917G>T p.E639D | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.69G>A p.Q23= | Splice Region (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- ADGB | c.2827C>G p.L943V | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ADIPOQ | c.506A>G p.K169R | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- AKAP6 | c.6595A>G p.S2199G | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AMER1 | c.3154C>A p.L1052M | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); called by muse, mutect2
- ANHX | c.432del p.R145Efs*14 | Frame Shift Del (DEL) | VAF 25/187 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.7468G>T p.D2490Y | Missense Mutation (SNP) | VAF 102/433 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, varscan2
- ANO10 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ANO5 | c.1610C>A p.S537Y | Missense Mutation (SNP) | VAF 44/684 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ARHGAP23 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF37 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, varscan2
- ARMC3 | c.2597C>A p.A866D | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARMC4 | c.1933C>A p.H645N | Missense Mutation (SNP) | VAF 74/461 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ARR3 | c.596G>A p.W199* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- ARR3 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 19/109 reads (17%) | called by muse, mutect2, varscan2
- ASB4 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, varscan2
- ATG4C | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2
- ATP13A4 | c.1295G>T p.R432M | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- ATP1A2 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN1 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 75/422 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- AZU1 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- BAHCC1 | c.2267A>G p.E756G | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2
- BBX | c.233A>T p.Q78L | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- BEND6 | c.557A>T p.K186M | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- BMX | c.443C>A p.A148E | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BNIP5 | c.1409A>C p.K470T | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2
- BTBD17 | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- C12orf4 | c.1434G>T p.M478I | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- C2CD3 | c.6754A>G p.R2252G | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- C4BPB | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C6 | c.1666T>A p.S556T | Missense Mutation (SNP) | VAF 36/481 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- C7orf50 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); called by muse, mutect2
- CA10 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 29/463 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- CALCR | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CALN1 | c.412C>A p.H138N (on ENST00000329008 / NM_001017440.3; = p.H180N on NM_031468.4) | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CAVIN2 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- CBL | c.691A>T p.T231S | Missense Mutation (SNP) | VAF 45/661 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); called by muse, mutect2
- CCDC168 | c.13249G>C p.E4417Q | Missense Mutation (SNP) | VAF 35/454 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- CCDC168 | c.12780G>C p.K4260N | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.607); called by muse, mutect2
- CCDC175 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2
- CCDC178 | c.728A>C p.Q243P | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, varscan2
- CCDC77 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- CCHCR1 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, varscan2
- CCT8L2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- CD1C | c.77T>A p.V26D | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2
- CD300LG | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 35/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CDA | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.061); called by muse, mutect2
- CDC14A | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 53/548 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- CDH8 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 81/585 reads (14%) | called by muse, mutect2, varscan2
- CENPE | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- CFAP47 | c.8523G>A p.M2841I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CFAP54 | c.5378T>A p.L1793H | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP94 | c.1819G>C p.A607P (on ENST00000320267 / NM_001352064.2; = p.A613P on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CIAO1 | c.489+1G>A p.X163_splice | Splice Site (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- COL24A1 | c.2310G>A p.E770= | Splice Region (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- COL4A5 | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 72/459 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- COL5A3 | c.3271G>A p.G1091S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL8A1 | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- CPA2 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- CPS1 | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 54/634 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- CRYBG1 | c.5347G>T p.E1783* | Nonsense Mutation (SNP) | VAF 35/445 reads (8%) | called by muse, mutect2
- CRYBG3 | c.450T>A p.D150E | Missense Mutation (SNP) | VAF 29/470 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2
- CSMD3 | c.6404T>A p.L2135* (on ENST00000297405 / NM_001363185.1; = p.L2031* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 35/887 reads (4%) | called by muse, mutect2
- CTNNA3 | c.2165A>G p.K722R | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CUL4B | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 72/456 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, varscan2
- CWC22 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 21/418 reads (5%) | called by muse, mutect2
- CX3CL1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYFIP1 | c.2480A>C p.E827A | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DDX53 | c.1280T>C p.I427T | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.89); called by muse, mutect2
- DENND2B | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by muse, varscan2
- DGKE | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DGKK | c.3585C>A p.D1195E | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.081); called by muse, mutect2
- DGKK | c.2098A>G p.I700V | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- DMXL1 | c.8021C>T p.A2674V | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
- DNAH11 | c.5160A>T p.E1720D | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DSE | c.2096G>A p.W699* | Nonsense Mutation (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- EBF1 | c.1436C>A p.T479N | Missense Mutation (SNP) | VAF 33/378 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- EBF3 | c.1155C>A p.D385E (on ENST00000355311 / NM_001375392.1; = p.D376E on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.155); called by muse, mutect2
- EFNB2 | c.12A>T p.R4S | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMCN | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- ENPP1 | c.1182G>C p.Q394H | Missense Mutation (SNP) | VAF 44/680 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ENPP6 | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ERC2 | c.1863G>C p.E621D | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.116); called by muse, mutect2
- ESCO1 | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ETFDH | c.839T>A p.V280D | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by mutect2, varscan2
- F8 | c.4107C>G p.S1369R | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- FAM205A | c.2359G>A p.G787R | Missense Mutation (SNP) | VAF 69/551 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASLG | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 69/436 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAT1 | c.1569A>T p.E523D | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT3 | c.4894A>G p.T1632A | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- FBXO39 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 39/499 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- FGD1 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2
- FGF13 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FOSL2 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXP4 | c.1426A>T p.I476F (on ENST00000307972 / NM_001012426.1; = p.I463F on NM_138457.3) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM2 | c.2390C>A p.T797N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by mutect2, varscan2
- FREM2 | c.7373T>A p.F2458Y | Missense Mutation (SNP) | VAF 28/621 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.105); called by muse, mutect2
- FRMPD3 | c.5096T>A p.L1699Q | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- G2E3 | c.2062A>T p.T688S | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRQ | c.342del p.W114* | Frame Shift Del (DEL) | VAF 62/348 reads (18%) | called by mutect2, pindel*, varscan2
- GOLGA8M | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 63/485 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR119 | c.860del p.R287Hfs*9 | Frame Shift Del (DEL) | VAF 31/218 reads (14%) | called by mutect2, pindel, varscan2
- GPR68 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- GPRASP2 | c.1559C>A p.A520D | Missense Mutation (SNP) | VAF 23/462 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2
- GRIN2B | c.2308T>A p.S770T | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- GTF2A1 | c.1128G>T p.W376C | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTF3C1 | c.2513G>T p.R838M | Missense Mutation (SNP) | VAF 67/367 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HERC1 | c.1852A>T p.K618* | Nonsense Mutation (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- ICE1 | c.6736G>T p.V2246F | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- IFT140 | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGHA2 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 23/494 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2
- IGKV1D-16 | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 58/749 reads (8%) | called by muse, mutect2
- IL21R | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.178); called by muse, mutect2
- ITGA4 | c.2491T>G p.S831A | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- ITGA8 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2
- ITSN2 | c.5083A>G p.T1695A | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2
- KAT6A | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KATNIP | c.2566_2567delinsT p.G856Sfs*141 | Frame Shift Del (DEL) | VAF 13/129 reads (10%) | called by pindel, varscan2*
- KCTD7 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- KDM3A | c.3709C>A p.L1237I | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIF26A | c.4052G>A p.G1351D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KIF3C | c.1773C>G p.L591= | Splice Region (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2
- KIF5C | c.2564del p.N855Tfs*29 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- KLK3 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KY | c.766C>G p.Q256E | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2
- LAIR2 | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LAMP5 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAS1L | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 46/437 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRB1 | c.113C>T p.T38I (on ENST00000427581; = p.T2I on NM_006669.6) | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, varscan2
- LRFN1 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, varscan2
- LRIT3 | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC7 | c.2126A>G p.E709G (on ENST00000651989 / NM_001370785.2; = p.E676G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LRRIQ1 | c.4565G>T p.W1522L | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRIQ1 | c.4566G>T p.W1522C | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAFA | c.976G>C p.A326P | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2
- MAGEE1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAMLD1 | c.99A>G p.G33= | Splice Region (SNP) | VAF 98/801 reads (12%) | called by muse, mutect2, varscan2
- MEGF6 | c.4442G>A p.G1481D | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MEGF9 | c.1043G>C p.R348P | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MLLT1 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MOAP1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2
- MORF4L1 | c.958G>C p.E320Q (on ENST00000331268 / NM_206839.2; = p.E281Q on NM_006791.4) | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MRM1 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MSN | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MUC16 | c.19916C>T p.P6639L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- MUC19 | c.1505G>T p.C502F | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0); called by muse, varscan2
- MYBL2 | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MYCBP2 | c.2603A>G p.H868R (on ENST00000357337; = p.H906R on NM_015057.5) | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.101); called by muse, mutect2
- NALCN | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 25/331 reads (8%) | called by muse, mutect2
- NAV3 | c.5576_5577del p.T1859Sfs*2 (on ENST00000397909 / NM_001024383.2; = p.T1837Sfs*2 on NM_014903.6) | Frame Shift Del (DEL) | VAF 60/420 reads (14%) | called by pindel, varscan2
- NBEA | c.2182G>T p.A728S | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NEGR1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- NELL1 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- NEXMIF | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 56/381 reads (15%) | called by muse, mutect2, varscan2
- NLRP12 | c.1926del p.S643Pfs*12 | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | called by mutect2, pindel, varscan2
- NLRP14 | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME8 | c.15dup p.R6Tfs*11 | Frame Shift Ins (INS) | VAF 90/881 reads (10%) | called by pindel, varscan2
- NOMO1 | c.805T>C p.C269R | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOTCH1 | c.2461T>A p.Y821N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NPC1L1 | c.334del p.R112Afs*10 | Frame Shift Del (DEL) | VAF 39/235 reads (17%) | called by mutect2, pindel, varscan2
- NSG2 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- NUP160 | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR10AG1 | c.591del p.F197Lfs*8 | Frame Shift Del (DEL) | VAF 54/440 reads (12%) | called by mutect2, pindel, varscan2
- OR10Z1 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- OR11H2 | c.587C>G p.A196G (on ENST00000556246; = p.A207G on NM_001197287.1) | Missense Mutation (SNP) | VAF 97/880 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- OR11H4 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2M3 | c.391A>T p.R131* | Nonsense Mutation (SNP) | VAF 86/327 reads (26%) | called by muse, mutect2, varscan2
- OR2M7 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- OR51Q1 | c.295T>A p.C99S | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5AR1 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5K4 | c.595A>T p.I199L | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR6N2 | c.525A>T p.Q175H | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.826); called by muse, mutect2
- OTOG | c.7409C>A p.P2470Q | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2
- OTOG | c.7996G>A p.E2666K | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OVCH1 | c.1562T>A p.L521* | Nonsense Mutation (SNP) | VAF 27/206 reads (13%) | called by muse, mutect2, varscan2
- OXGR1 | c.986A>T p.K329M | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.417); called by muse, varscan2
- PAMR1 | c.1636A>G p.I546V (on ENST00000619888 / NM_001001991.3; = p.I563V on NM_015430.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH15 | c.5080G>C p.A1694P | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- PCDH18 | c.2830A>T p.R944W | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHB2 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- PCDHGA5 | c.1933G>T p.A645S | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PDE4A | c.2160A>T p.E720D (on ENST00000380702 / NM_001111307.2; = p.E481D on NM_006202.3) | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PEX5 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 139/1027 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PHKA2 | c.3666T>A p.Y1222* | Nonsense Mutation (SNP) | VAF 39/728 reads (5%) | called by muse, mutect2
- PHLPP2 | c.736-2A>G p.X246_splice | Splice Site (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2
- PI4K2B | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PIAS2 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PKDREJ | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCXD3 | c.104-2del p.X35_splice | Splice Site (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- PPIAL4A | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 174/1288 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); called by muse, varscan2
- PPIL2 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRIM2 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRR16 | c.298_308del p.N100Yfs*2 (on ENST00000407149 / NM_001300783.2; = p.N77Yfs*2 on NM_016644.2) | Frame Shift Del (DEL) | VAF 18/228 reads (8%) | called by mutect2, pindel
- RASAL2 | c.1252A>T p.S418C | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- RBMX | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RELN | c.2660T>A p.L887H | Missense Mutation (SNP) | VAF 87/544 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RFX6 | c.2033G>T p.C678F | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.361); called by muse, mutect2
- RINL | c.860C>T p.S287L (on ENST00000591812 / NM_001195833.2; = p.S173L on NM_198445.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RIPOR3 | c.1847C>A p.P616Q | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RMI1 | c.824C>A p.S275* | Nonsense Mutation (SNP) | VAF 30/319 reads (9%) | called by muse, mutect2
- RNF128 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RNF17 | c.4360G>T p.E1454* | Nonsense Mutation (SNP) | VAF 42/485 reads (9%) | called by muse, mutect2
- RNF25 | c.477C>G p.C159W | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RNF31 | c.1796T>A p.F599Y | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- RNF40 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RPGRIP1L | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 96/678 reads (14%) | called by muse, varscan2
- RRP8 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SEC61B | c.261G>T p.L87F | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEC63 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 66/990 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA5A | c.1672A>T p.S558C | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2
- SEMA6D | c.2485_2487del p.V829del (on ENST00000316364 / NM_153618.2; = p.V767del on NM_020858.2) | In Frame Del (DEL) | VAF 82/618 reads (13%) | called by pindel, varscan2
- SERPINI2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 25/513 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2
- SH3BP4 | c.80G>C p.S27T | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- SIGLEC11 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2
- SIM1 | c.1438G>T p.G480* | Nonsense Mutation (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK2 | c.1596C>A p.D532E | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SMARCA1 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SOWAHD | c.658A>G p.S220G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SPIC | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.161); called by muse, mutect2
- SRA1 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 39/574 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- STON1-GTF2A1L | c.3258G>T p.K1086N | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- SV2C | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SYNE1 | c.18208-2A>T p.X6070_splice (on ENST00000367255 / NM_182961.4; = p.X5999_splice on NM_033071.3) | Splice Site (SNP) | VAF 119/648 reads (18%) | called by muse, mutect2, varscan2
- SYNE1 | c.12329A>T p.D4110V (on ENST00000367255 / NM_182961.4; = p.D4039V on NM_033071.3) | Missense Mutation (SNP) | VAF 53/738 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- SYT16 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.059); called by muse, varscan2
- TAZ | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 67/338 reads (20%) | called by muse, mutect2, varscan2
- TBC1D22A | c.1101G>T p.M367I | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBL1X | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- TCEAL6 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 17/419 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); called by muse, mutect2
- TIMM8A | c.189T>A p.F63L | Missense Mutation (SNP) | VAF 92/501 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132C | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM200A | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM200C | c.396G>T p.R132S | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TMEM200C | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMIGD3 | c.292C>A p.H98N (on ENST00000369717 / NM_001081976.2; = p.H179N on NM_020683.7) | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TNRC18 | c.1855A>T p.M619L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, varscan2
- TRAF4 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TRERF1 | c.1603G>T p.G535W | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM21 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- TRIM29 | c.570C>A p.C190* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | called by muse, mutect2, varscan2
- TRIM51GP | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 84/598 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- TTN | c.94700G>T p.G31567V (on ENST00000591111; = p.G24143V on NM_003319.4) | Missense Mutation (SNP) | VAF 13/181 reads (7%) | PolyPhen benign (0.167); called by muse, mutect2
- TTN | c.94699G>T p.G31567* (on ENST00000591111; = p.G24143* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- TTN | c.40562del p.G13521Efs*15 (on ENST00000591111; = p.G6097Efs*15 on NM_003319.4) | Frame Shift Del (DEL) | VAF 64/630 reads (10%) | called by mutect2, pindel, varscan2
- TTN | c.608A>T p.K203M | Missense Mutation (SNP) | VAF 43/732 reads (6%) | PolyPhen possibly damaging (0.858); called by muse, mutect2
- UGT1A7 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.098); called by muse, mutect2
- UGT2A1 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC80 | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.743); called by muse, mutect2
- UPF3B | c.1280A>G p.K427R (on ENST00000276201 / NM_080632.3; = p.K414R on NM_023010.3) | Missense Mutation (SNP) | VAF 52/425 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- USH2A | c.11187T>A p.S3729R | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- WASHC4 | c.3355-2A>T p.X1119_splice | Splice Site (SNP) | VAF 59/390 reads (15%) | called by muse, mutect2, varscan2
- XIRP2 | c.8773C>T p.Q2925* (on ENST00000628543; = p.Q3100* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 74/427 reads (17%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, varscan2
- ZFHX2 | c.6080C>T p.A2027V | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2
- ZFHX4 | c.3298G>T p.V1100F | Missense Mutation (SNP) | VAF 71/378 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ZNF148 | c.2128A>C p.T710P | Missense Mutation (SNP) | VAF 74/655 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ZNF266 | c.1133G>T p.R378M | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ZNF320 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF37A | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF440 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, varscan2
- ZNF536 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF585A | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.846); called by muse, mutect2
- ZNF99 | c.1306C>A p.R436S | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZPBP | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ABCA13 | c.2076A>G p.Q692= | Silent (SNP) | VAF 33/302 reads (11%) | called by muse, mutect2, varscan2
- ABCA3 | c.3387T>C p.H1129= | Silent (SNP) | VAF 32/392 reads (8%) | catalogued as rs770795063; called by muse, mutect2
- ACY3 | c.156G>T p.L52= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ADPRH | c.456C>T p.I152= | Silent (SNP) | VAF 34/635 reads (5%) | called by muse, mutect2
- ATP4A | c.2439C>T p.L813= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs147416424; called by muse, mutect2
- ATP7A | c.2340C>T p.F780= | Silent (SNP) | VAF 79/492 reads (16%) | called by muse, mutect2, varscan2
- BFAR | c.339C>A p.V113= | Silent (SNP) | VAF 21/442 reads (5%) | called by muse, mutect2
- CACNA2D2 | c.2202G>A p.T734= (on ENST00000479441 / NM_001174051.3; = p.T727= on NM_006030.4) | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as rs369166288; called by muse, mutect2, varscan2
- CADPS2 | c.108G>A p.P36= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1230917610; called by muse, mutect2, varscan2
- CARMIL1 | c.684A>G p.L228= | Silent (SNP) | VAF 75/354 reads (21%) | called by muse, mutect2, varscan2
- CD8B | c.210G>A p.L70= | Silent (SNP) | VAF 46/197 reads (23%) | catalogued as rs753332620; called by muse, mutect2, varscan2
- CLEC3A | c.150T>C p.D50= (on ENST00000651443; = p.D41= on NM_005752.6) | Silent (SNP) | VAF 48/336 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.3090A>G p.S1030= | Silent (SNP) | VAF 60/392 reads (15%) | called by muse, varscan2
- COL14A1 | c.4719T>C p.I1573= | Silent (SNP) | VAF 56/235 reads (24%) | called by muse, mutect2, varscan2
- COL17A1 | c.3012G>A p.P1004= | Silent (SNP) | VAF 34/408 reads (8%) | catalogued as rs368653483, COSV62227161, COSV62229518; called by muse, mutect2
- COL3A1 | c.651T>C p.P217= | Silent (SNP) | VAF 70/416 reads (17%) | called by muse, mutect2, varscan2
- COL4A4 | c.2241C>A p.P747= | Silent (SNP) | VAF 64/342 reads (19%) | catalogued as rs374510402; called by muse, mutect2, varscan2
- CPA3 | c.1251C>A p.S417= | Silent (SNP) | VAF 30/120 reads (25%) | called by muse, varscan2
- CSMD1 | c.4452G>T p.V1484= (on ENST00000520002; = p.V1483= on NM_033225.6) | Silent (SNP) | VAF 29/348 reads (8%) | catalogued as COSV100150600; called by muse, mutect2
- CSMD3 | c.9379C>A p.R3127= (on ENST00000297405 / NM_001363185.1; = p.R2958= on NM_052900.3) | Silent (SNP) | VAF 78/676 reads (12%) | catalogued as COSV52211222; called by mutect2, varscan2
- DIAPH1 | c.3687C>G p.V1229= | Silent (SNP) | VAF 30/369 reads (8%) | called by muse, mutect2
- DNAJC6 | c.1398G>T p.P466= | Silent (SNP) | VAF 43/259 reads (17%) | called by muse, mutect2, varscan2
- EIF3H | c.153A>G p.K51= | Silent (SNP) | VAF 21/255 reads (8%) | called by muse, mutect2
- EPHA7 | c.2754C>T p.N918= | Silent (SNP) | VAF 29/300 reads (10%) | called by muse, mutect2
- ERBB4 | c.2463T>A p.L821= | Silent (SNP) | VAF 103/762 reads (14%) | catalogued as rs376971305; called by muse, mutect2, varscan2
- ERBB4 | c.1251T>C p.F417= | Silent (SNP) | VAF 40/522 reads (8%) | called by muse, mutect2
- ERICH3 | c.3015G>A p.R1005= | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as COSV58619672; called by muse, mutect2
- ESRRB | c.267C>T p.I89= | Silent (SNP) | VAF 28/389 reads (7%) | called by muse, mutect2
- EYS | c.3720A>T p.I1240= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- F8 | c.2025T>C p.Y675= | Silent (SNP) | VAF 95/487 reads (20%) | called by muse, mutect2, varscan2
- F9 | c.1032C>T p.I344= | Silent (SNP) | VAF 38/292 reads (13%) | catalogued as rs886038243, COSV54382874; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT1 | c.4377A>G p.S1459= | Silent (SNP) | VAF 85/538 reads (16%) | catalogued as rs765115417; called by muse, mutect2, varscan2
- FAT3 | c.5310C>G p.L1770= | Silent (SNP) | VAF 23/427 reads (5%) | called by muse, mutect2
- FHAD1 | c.1176G>T p.S392= | Silent (SNP) | VAF 39/187 reads (21%) | catalogued as COSV62717516; called by muse, mutect2, varscan2
- FOSL2 | c.420G>A p.K140= | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- FREM2 | c.3468G>A p.V1156= | Silent (SNP) | VAF 33/311 reads (11%) | called by muse, mutect2, varscan2
- GABRE | c.876G>T p.T292= | Silent (SNP) | VAF 50/308 reads (16%) | called by muse, mutect2, varscan2
- GLB1L3 | c.132G>T p.A44= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV66283352; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1551G>A p.E517= | Silent (SNP) | VAF 40/273 reads (15%) | catalogued as rs1427468253; called by mutect2, varscan2
- GOLGA6L22 | c.165C>T p.C55= | Silent (SNP) | VAF 21/383 reads (5%) | catalogued as rs757416537; called by muse, mutect2
- GPR12 | c.633G>T p.A211= | Silent (SNP) | VAF 30/414 reads (7%) | catalogued as COSV67343995; called by muse, mutect2
- GRIA1 | c.1434G>T p.V478= | Silent (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- GRM1 | c.861G>T p.V287= | Silent (SNP) | VAF 47/424 reads (11%) | called by muse, mutect2, varscan2
- GRM1 | c.3174C>T p.P1058= | Silent (SNP) | VAF 24/197 reads (12%) | catalogued as rs1037209850, COSV51295437; called by muse, mutect2, varscan2
- HCN1 | c.2349C>A p.V783= | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as COSV57513136; called by muse, mutect2, varscan2
- HCRTR2 | c.672C>T p.H224= | Silent (SNP) | VAF 15/354 reads (4%) | catalogued as rs1200607235; called by muse, mutect2
- HNF1B | c.1521G>A p.L507= | Silent (SNP) | VAF 28/446 reads (6%) | catalogued as rs1186457589; called by muse, mutect2
- IFT80 | c.1338A>G p.S446= | Silent (SNP) | VAF 26/610 reads (4%) | called by muse, mutect2
- INO80E | c.423C>T p.F141= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- KCNH1 | c.1284C>A p.T428= (on ENST00000271751 / NM_172362.3; = p.T401= on NM_002238.4) | Silent (SNP) | VAF 40/520 reads (8%) | called by muse, mutect2
- KCNH7 | c.315T>C p.T105= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as rs749312659; called by muse, mutect2, varscan2
- KCNQ3 | c.1279T>C p.L427= | Silent (SNP) | VAF 53/1061 reads (5%) | called by muse, mutect2
- KLHDC7A | c.1587G>A p.V529= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- KRT73 | c.222C>G p.G74= | Silent (SNP) | VAF 38/284 reads (13%) | catalogued as COSV59837831; called by muse, mutect2, varscan2
- KRTAP13-2 | c.420C>T p.L140= | Silent (SNP) | VAF 18/249 reads (7%) | catalogued as rs748883950, COSV67761871; called by muse, mutect2
- KRTAP5-5 | c.693G>T p.V231= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, varscan2
- LPIN1 | c.1338C>T p.G446= | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- LRP1B | c.6177T>C p.A2059= | Silent (SNP) | VAF 36/263 reads (14%) | called by muse, mutect2
- LRRC69 | c.249A>G p.T83= | Silent (SNP) | VAF 11/294 reads (4%) | called by muse, mutect2
- MACF1 | c.2304G>A p.L768= | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- MAGEA4 | c.411G>T p.L137= | Silent (SNP) | VAF 49/296 reads (17%) | called by muse, mutect2, varscan2
- MAGEE1 | c.1098C>T p.T366= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as COSV63911911; called by muse, mutect2, varscan2
- MAP3K20 | c.144C>T p.L48= | Silent (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- MECOM | c.135T>C p.S45= (on ENST00000468789 / NM_001105078.4; = p.S233= on NM_004991.4) | Silent (SNP) | VAF 58/1100 reads (5%) | called by muse, mutect2
- MFAP1 | c.345G>A p.E115= | Silent (SNP) | VAF 34/482 reads (7%) | called by muse, mutect2
- MFSD1 | c.48T>A p.P16= | Silent (SNP) | VAF 52/322 reads (16%) | called by muse, mutect2, varscan2
- MINAR2 | c.486T>C p.H162= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- MOAP1 | c.294A>T p.P98= | Silent (SNP) | VAF 30/266 reads (11%) | catalogued as COSV52092280; called by muse, mutect2
- MTERF1 | c.372C>T p.I124= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV61098894; called by muse, mutect2, varscan2
- MUC6 | c.141G>A p.T47= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs369660838; called by muse, mutect2
- NAV3 | c.5436A>G p.L1812= (on ENST00000397909 / NM_001024383.2; = p.L1790= on NM_014903.6) | Silent (SNP) | VAF 23/274 reads (8%) | called by muse, mutect2
- NCSTN | c.459G>A p.G153= | Silent (SNP) | VAF 173/792 reads (22%) | catalogued as rs201446902; called by muse, mutect2, varscan2
- NDUFA9 | c.828G>T p.L276= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as COSV56929800; called by muse, mutect2, varscan2
- NEDD4 | c.2436C>T p.S812= (on ENST00000508342 / NM_001284338.1; = p.S393= on NM_006154.4) | Silent (SNP) | VAF 56/355 reads (16%) | called by muse, mutect2, varscan2
- NOS2 | c.2145A>G p.S715= | Silent (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1074G>A p.K358= | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- NPR2 | c.1644C>T p.V548= | Silent (SNP) | VAF 127/748 reads (17%) | catalogued as rs772510686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD2 | c.2076C>T p.L692= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as rs1252945475; called by muse, mutect2
- NUDT9 | c.15C>A p.L5= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- OPTC | c.687C>A p.R229= | Silent (SNP) | VAF 129/391 reads (33%) | called by muse, mutect2, varscan2
- OR6X1 | c.255G>T p.V85= | Silent (SNP) | VAF 21/217 reads (10%) | catalogued as COSV100020623; called by muse, mutect2
- PARD3 | c.873C>T p.F291= | Silent (SNP) | VAF 21/360 reads (6%) | called by muse, mutect2
- PCDHB3 | c.1488G>T p.P496= | Silent (SNP) | VAF 127/638 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1872C>T p.G624= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs568102289; called by muse, mutect2
- PCLO | c.13062G>T p.V4354= | Silent (SNP) | VAF 56/438 reads (13%) | called by muse, mutect2, varscan2
- PDGFRA | c.174G>A p.Q58= | Silent (SNP) | VAF 35/320 reads (11%) | catalogued as rs1484593114, COSV57267626; called by muse, mutect2, varscan2
- PDZRN4 | c.2478C>T p.H826= (on ENST00000402685 / NM_001164595.2; = p.H568= on NM_013377.4) | Silent (SNP) | VAF 30/457 reads (7%) | called by muse, mutect2
- PFKFB1 | c.1342C>A p.R448= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as COSV51498327; called by muse, mutect2, varscan2
- PHETA2 | c.411C>T p.D137= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as rs780344347; called by muse, mutect2, varscan2
- PHLDB1 | c.3420G>A p.A1140= | Silent (SNP) | VAF 18/207 reads (9%) | catalogued as rs145931359; called by muse, mutect2
- PIK3C3 | c.1059A>G p.G353= | Silent (SNP) | VAF 34/338 reads (10%) | catalogued as rs779307383; called by muse, mutect2
- PIK3CG | c.465G>T p.T155= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs763026770, COSV63245360; called by muse, mutect2, varscan2
- PITPNM2 | c.1011G>A p.S337= | Silent (SNP) | VAF 44/224 reads (20%) | catalogued as rs369669482; called by muse, mutect2, varscan2
- PODXL2 | c.486G>A p.E162= | Silent (SNP) | VAF 133/597 reads (22%) | called by muse, mutect2, varscan2
- POLR1B | c.1701T>C p.D567= | Silent (SNP) | VAF 36/309 reads (12%) | called by muse, mutect2, varscan2
- POU3F2 | c.477T>A p.A159= | Silent (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- PPA2 | c.300G>C p.R100= | Silent (SNP) | VAF 31/396 reads (8%) | called by muse, mutect2
- PRAG1 | c.3873C>G p.P1291= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as rs1182329401; called by muse, mutect2, varscan2
- PRKCSH | c.1131C>T p.F377= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as rs371089264, COSV52951403; called by muse, mutect2, varscan2
- PRR12 | c.204G>T p.P68= (on ENST00000615927; = p.P889= on NM_020719.3) | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- PSEN2 | c.528A>T p.S176= | Silent (SNP) | VAF 242/808 reads (30%) | called by muse, mutect2, varscan2
- PYGL | c.834G>T p.R278= | Silent (SNP) | VAF 52/937 reads (6%) | called by muse, mutect2
- QRFPR | c.274C>T p.L92= | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as rs570036605; called by muse, mutect2, varscan2
- RABEP2 | c.1020C>T p.N340= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- RASAL2 | c.1251T>C p.S417= | Silent (SNP) | VAF 47/382 reads (12%) | called by muse, varscan2
- REG3A | c.60G>T p.L20= | Silent (SNP) | VAF 29/254 reads (11%) | called by muse, mutect2, varscan2
- RELN | c.5565T>C p.D1855= | Silent (SNP) | VAF 17/332 reads (5%) | called by muse, mutect2
- RGPD3 | c.5166C>T p.F1722= | Silent (SNP) | VAF 68/968 reads (7%) | catalogued as rs1166352730, COSV58748477; called by muse, mutect2
- RHAG | c.214C>T p.L72= | Silent (SNP) | VAF 90/623 reads (14%) | called by muse, varscan2
- RORB | c.456T>C p.Y152= (on ENST00000396204 / NM_001365023.1; = p.Y141= on NM_006914.4) | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as rs149294914; called by muse, mutect2, varscan2
- RTN3 | c.2076C>G p.V692= (on ENST00000377819 / NM_001265589.2; = p.V673= on NM_201428.3) | Silent (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2, varscan2
- SCN10A | c.1899C>A p.P633= | Silent (SNP) | VAF 43/209 reads (21%) | called by muse, mutect2, varscan2
- SLC20A2 | c.1941G>C p.G647= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as COSV60601565; called by muse, mutect2, varscan2
- SLC28A3 | c.1038G>T p.L346= | Silent (SNP) | VAF 39/196 reads (20%) | called by muse, mutect2, varscan2
- SLC4A8 | c.2250C>T p.V750= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs762924472; called by muse, mutect2
- SLITRK3 | c.1473C>G p.V491= | Silent (SNP) | VAF 25/537 reads (5%) | called by muse, mutect2
- SOX3 | c.870G>T p.P290= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- SPART | c.646C>T p.L216= | Silent (SNP) | VAF 99/696 reads (14%) | called by muse, mutect2, varscan2
- SPATA5 | c.549C>T p.F183= | Silent (SNP) | VAF 19/98 reads (19%) | called by muse, varscan2
- SPEF2 | c.2181T>C p.F727= | Silent (SNP) | VAF 57/334 reads (17%) | catalogued as COSV61551298; called by muse, mutect2, varscan2
- STAP1 | c.807T>C p.C269= | Silent (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- STARD8 | c.657G>C p.V219= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- SYT9 | c.1272C>T p.V424= | Silent (SNP) | VAF 15/447 reads (3%) | catalogued as COSV59614546; called by muse, mutect2
- TAAR6 | c.133C>T p.L45= | Silent (SNP) | VAF 26/528 reads (5%) | catalogued as COSV51583450, COSV51584281; called by muse, mutect2
- TAS2R60 | c.624C>T p.V208= | Silent (SNP) | VAF 44/568 reads (8%) | called by muse, mutect2
- TMED10 | c.372A>T p.L124= | Silent (SNP) | VAF 56/719 reads (8%) | catalogued as rs775535283; called by muse, mutect2
- TMED3 | c.444G>A p.E148= | Silent (SNP) | VAF 30/324 reads (9%) | catalogued as rs1360046695; called by muse, mutect2
- TNRC18 | c.1809C>G p.R603= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, varscan2
- TTC37 | c.1473T>C p.Y491= | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- TTC6 | c.2520G>T p.R840= | Silent (SNP) | VAF 157/534 reads (29%) | called by muse, mutect2, varscan2
- UNC5D | c.2244T>C p.F748= | Silent (SNP) | VAF 40/374 reads (11%) | called by muse, mutect2, varscan2
- USH2A | c.5658C>A p.V1886= | Silent (SNP) | VAF 153/709 reads (22%) | called by muse, mutect2, varscan2
- VAX1 | c.393C>G p.T131= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV53327888; called by muse, mutect2
- VGLL3 | c.432T>C p.N144= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- WDFY3 | c.3966G>T p.V1322= | Silent (SNP) | VAF 30/289 reads (10%) | called by muse, mutect2, varscan2
- ZIC3 | c.348C>A p.R116= | Silent (SNP) | VAF 40/163 reads (25%) | called by muse, mutect2, varscan2
- ZNF235 | c.1143G>A p.G381= | Silent (SNP) | VAF 50/271 reads (18%) | called by muse, mutect2, varscan2
- ZNF273 | c.171A>G p.S57= | Silent (SNP) | VAF 34/425 reads (8%) | called by muse, mutect2
- ZNF682 | c.369T>C p.C123= | Silent (SNP) | VAF 12/292 reads (4%) | called by muse, mutect2
- ZNF727 | c.624C>A p.A208= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4047A>C | RNA (SNP) | VAF 50/422 reads (12%) | called by muse, mutect2, varscan2
- AC091304.1 | n.483G>T | RNA (SNP) | VAF 52/886 reads (6%) | called by muse, mutect2
- AC112721.1 | n.265T>G | RNA (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2
- AC131280.1 | chr15:20669608 A>T | 3'Flank (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- AC235097.1 | n.163G>T | RNA (SNP) | VAF 86/452 reads (19%) | called by muse, mutect2, varscan2
- ACSL1 | c.-33+4820A>T | Intron (SNP) | VAF 25/372 reads (7%) | called by muse, mutect2
- ACTG1 | c.*609G>A | 3'UTR (SNP) | VAF 40/200 reads (20%) | catalogued as rs1444172034; called by muse, varscan2
- ADGRD1 | c.188-2391C>A | Intron (SNP) | VAF 42/285 reads (15%) | called by muse, mutect2, varscan2
- ALG13 | c.-8C>A | 5'UTR (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- AP003062.1 | n.1005C>A | RNA (SNP) | VAF 24/180 reads (13%) | called by muse, mutect2, varscan2
- APOOL | c.-34C>G | 5'UTR (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- ARL13B | c.*2109G>T | 3'UTR (SNP) | VAF 13/262 reads (5%) | called by muse, mutect2
- AVPR1A | c.*2009C>A | 3'UTR (SNP) | VAF 56/392 reads (14%) | called by muse, mutect2, varscan2
- BCORL1 | c.4306-2787T>A | Intron (SNP) | VAF 94/648 reads (15%) | called by muse, mutect2, varscan2
- CACNA1F | c.4986+23C>A | Intron (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- CCZ1B | c.218+36A>G | Intron (SNP) | VAF 41/319 reads (13%) | called by muse, mutect2, varscan2
- CGB7 | c.-858T>A | 5'UTR (SNP) | VAF 8/65 reads (12%) | catalogued as rs1221574152; called by muse, mutect2, varscan2
- CLRN1 | c.*829A>C | 3'UTR (SNP) | VAF 48/760 reads (6%) | catalogued as rs1460960979; called by muse, mutect2
- COQ10B | c.104+357G>T | Intron (SNP) | VAF 41/462 reads (9%) | called by muse, mutect2
- DCHS2 | n.6996A>G | RNA (SNP) | VAF 41/281 reads (15%) | catalogued as rs1560971191; called by muse, mutect2, varscan2
- DNAH14 | c.7486-3904A>T | Intron (SNP) | VAF 35/592 reads (6%) | called by muse, mutect2
- FAM184A | c.1653+9T>G | Intron (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- FMR1 | c.*618C>G | 3'UTR (SNP) | VAF 79/436 reads (18%) | called by muse, mutect2, varscan2
- GPM6A | c.-23+31413G>T | Intron (SNP) | VAF 41/432 reads (9%) | catalogued as COSV99702939; called by muse, mutect2
- HERC2P3 | n.346C>A | RNA (SNP) | VAF 23/222 reads (10%) | called by mutect2, varscan2
- IFI27 | c.283+141G>C | Intron (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- IGHE | c.*1C>T | 3'UTR (SNP) | VAF 11/92 reads (12%) | catalogued as rs781949381; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847902 G>C | 5'Flank (SNP) | VAF 93/1458 reads (6%) | called by muse, mutect2
- LGSN | c.163+1136T>C | Intron (SNP) | VAF 24/282 reads (9%) | called by muse, mutect2
- MAP2K3 | c.50-2648G>T | Intron (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- MAST4 | c.1591+28G>A | Intron (SNP) | VAF 23/275 reads (8%) | called by muse, mutect2
- MIR513A1 | n.125G>T | RNA (SNP) | VAF 42/261 reads (16%) | called by muse, mutect2, varscan2
- MIR517B | n.33C>T | RNA (SNP) | VAF 40/348 reads (11%) | catalogued as rs1323070812; called by muse, mutect2, varscan2
- MIR518E | n.41_85del | RNA (DEL) | VAF 35/227 reads (15%) | called by mutect2, pindel
- MIR587 | n.23A>G | RNA (SNP) | VAF 24/278 reads (9%) | catalogued as rs782155199; called by muse, mutect2
- MIR892B | n.73G>T | RNA (SNP) | VAF 68/422 reads (16%) | catalogued as rs1556968615; called by muse, mutect2, varscan2
- MLIP | c.613-11762C>G | Intron (SNP) | VAF 57/566 reads (10%) | called by muse, mutect2, varscan2
- MRPS36P1 | chr3:6770022 C>G | 3'Flank (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- NDRG4 | c.373-133G>A | Intron (SNP) | VAF 36/295 reads (12%) | called by muse, mutect2, varscan2
- NDST4 | c.2115+3095C>G | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- NPPB | c.*16G>A | 3'UTR (SNP) | VAF 20/268 reads (7%) | catalogued as COSV100916087; called by muse, mutect2
- NR5A2 | c.1110+8786G>T | Intron (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- OFCC1 | n.1741G>A | RNA (SNP) | VAF 17/229 reads (7%) | called by muse, mutect2
- PARP14 | c.4941+477G>T | Intron (SNP) | VAF 38/510 reads (7%) | catalogued as rs1407017392; called by muse, mutect2
- PDHA1 | c.*52C>T | 3'UTR (SNP) | VAF 33/691 reads (5%) | called by muse, mutect2
- PDZRN4 | c.844-46396G>A | Intron (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- PIEZO2 | c.7742+48C>A | Intron (SNP) | VAF 32/298 reads (11%) | called by muse, mutect2, varscan2
- PSG6 | c.*2C>T | 3'UTR (SNP) | VAF 16/214 reads (7%) | catalogued as rs753264217; called by muse, mutect2
- RDX | c.1345-35A>G | Intron (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- RN7SL214P | chr15:77915704 G>T | 3'Flank (SNP) | VAF 46/267 reads (17%) | catalogued as rs756627224; called by muse, mutect2, varscan2
- RPL18 | c.198+40C>T | Intron (SNP) | VAF 55/317 reads (17%) | catalogued as rs746217256; called by muse, mutect2, varscan2
- RPS6KA3 | c.-45G>T | 5'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- SEC61A2 | chr10:12169321 C>G | 3'Flank (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- SLC2A4RG | c.282-33G>C | Intron (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- SLC30A4 | c.391+962A>T | Intron (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- SLC66A1L | n.286A>G | RNA (SNP) | VAF 105/449 reads (23%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.1276+20G>T | Intron (SNP) | VAF 41/193 reads (21%) | called by muse, mutect2, varscan2
- SNRNP40 | c.1024+492A>G | Intron (SNP) | VAF 33/202 reads (16%) | called by muse, mutect2, varscan2
- TAF1 | c.5002-373G>C | Intron (SNP) | VAF 32/256 reads (13%) | called by muse, mutect2, varscan2
- TBX22 | c.356+13C>A | Intron (SNP) | VAF 82/457 reads (18%) | called by muse, mutect2, varscan2
- TCTEX1D1 | c.211+73G>A | Intron (SNP) | VAF 23/262 reads (9%) | called by muse, mutect2
- TMIGD3 | c.*25A>T | 3'UTR (SNP) | VAF 28/346 reads (8%) | called by muse, mutect2
- TSGA10 | c.-437A>T | 5'UTR (SNP) | VAF 18/310 reads (6%) | called by muse, mutect2
- TTN | c.10360+3734T>C | Intron (SNP) | VAF 28/442 reads (6%) | called by muse, mutect2
- UBE2M | c.-19C>T | 5'UTR (SNP) | VAF 13/68 reads (19%) | called by muse, varscan2
- VMA21 | chrX:151396983 G>C | 5'Flank (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- VMA21 | c.*28A>C | 3'UTR (SNP) | VAF 65/406 reads (16%) | called by muse, mutect2, varscan2
- XRN1 | c.-3G>T | 5'UTR (SNP) | VAF 52/400 reads (13%) | catalogued as rs757170186; called by muse, mutect2, varscan2
- ZNF849P | n.749del | RNA (DEL) | VAF 65/282 reads (23%) | called by mutect2, pindel, varscan2
